Gene-level copy-number profile of tumor specimen TCGA-AC-A7VB-01A from TCGA case TCGA-AC-A7VB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.5 years (18,806 days).
Specimen TCGA-AC-A7VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.3285e0c3-243c-41ac-b930-880af2f6ab87.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A7VB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e38020a-bde9-4b1d-991a-1bda3aca26e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 10,980; copy number 2: 42,088; copy number 3: 5,960; copy number 4: 266; copy number 5: 145; copy number 6: 85; copy number 7: 2; copy number 8: 25; copy number 9: 7; copy number 10: 24; copy number 11: 19; copy number 13: 54; copy number 14: 1; copy number 19: 79; copy number 20: 5; copy number 22: 50; copy number 28: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A7VB-01A-11D-A350-01): tumor purity 0.88, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:58,872,149–59,436,874, 8 genes (within-gene range 0–1): LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P.
- chr12:65,466,820–66,066,338, 14 genes (within-gene range 0–1): AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 497 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,067,441–38,853,028, 58 genes, copy number 8–13 (within-gene range 4–13): AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA.
- chr8:42,416,475–43,030,535, 15 genes, copy number 5 (within-gene range 1–5): SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA.
- chr8:60,046,755–60,868,028, 11 genes, copy number 5 (within-gene range 4–5): AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1.
- chr8:69,922,751–71,228,629, 25 genes, copy number 5 (within-gene range 3–5): RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1.
- chr8:104,489,231–106,060,524, 11 genes, copy number 5 (within-gene range 3–5): LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1.
- chr8:105,737,280–111,236,203, 57 genes, copy number 5–6: RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37.
- chr8:114,791,653–120,373,573, 53 genes, copy number 5–6: CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr12:40,393,395–41,072,415, 6 genes, copy number 5: MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.
- chr12:48,995,149–49,337,188, 22 genes, copy number 8–9: DDN, AC011603.3, DDN-AS1, PRKAG1, KMT2D, RHEBL1, AC011603.4, DHH, AC011603.1, LMBR1L, TUBA1B, AC011603.2, Y_RNA, TUBA1A, TUBA1C, Metazoa_SRP, AC010173.1, AC125611.3, AC125611.4, PRPH, TROAP, C1QL4.
- chr12:66,950,754–73,143,858, 113 genes, copy number 7–22 (broad region; genes not listed).
- chr12:73,764,279–73,764,413, 1 gene, copy number 5: U8.
- chr12:77,021,248–77,317,234, 3 genes, copy number 8: E2F7, AC079030.1, LINC02464.
- chr12:77,379,770–77,390,869, 1 gene, copy number 8: AC073591.1.
- chr12:83,151,331–83,172,740, 2 genes, copy number 8: RPL6P25, AC090680.1.
- chr12:91,050,491–93,516,214, 46 genes, copy number 5–28: KERA, LUM, DCN, AC007115.1, LINC02823, AC090016.1, AC126175.1, AC126175.2, AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7, EEA1, AC026111.1, HNRNPA1P50, RNU6-1329P, LINC02413, AC138123.1, Y_RNA, AC021646.1, RPL41P5, AC138123.2, NACAP8, LINC02412, AC126172.1, AC124947.2, AC124947.1, NUDT4, UBE2N, Y_RNA, MRPL42, RN7SL737P.
- chr16:12,901,598–13,563,388, 5 genes, copy number 10–14 (within-gene range 2–14): SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1.
- chr19:7,030,578–7,769,605, 37 genes, copy number 19: MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2, RPS27AP19, RETN, MCEMP1, AC008763.3, TRAPPC5, FCER2, CLEC4G, AC008763.4, CD209, RPL21P129, CLEC4M.
- chr21:37,607,373–39,183,488, 30 genes, copy number 6 (within-gene range 1–6): KCNJ6, KCNJ6-AS1, DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1.
- chr21:39,184,469–39,184,899, 1 gene, copy number 6: AF129408.1.

Autosomal genes at a single copy (total copy number 1): 10,980. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
